Somatic mutation profile of tumor specimen MMRF_1110_2_BM_CD138pos (aliquot MMRF_1110_2_BM_CD138pos_T1_KHS5U_L13760) from MMRF case MMRF_1110, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.6 years (25,408 days).
Specimen MMRF_1110_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b26304f3-06ab-484d-aac3-cab6c31475ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1110_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1110_2_PB_WBC_C3_KHS5U_L13761; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fdef3bd-f301-49a0-9418-f1a2e01d691a

The open-access MAF lists 176 somatic variants for this specimen: 73 protein-altering or splice-affecting, 24 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, 3'UTR 45, Silent 24, Intron 22, Splice Site 5, 5'Flank 4, 5'UTR 3, RNA 3, 3'Flank 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.456_458del p.P153del | In Frame Del (DEL) | VAF 52/185 reads (28%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AC099489.1 | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1257019134; called by muse, mutect2, varscan2
- ADAMTS20 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV67138089; called by muse, mutect2, varscan2
- ARHGEF33 | c.1308C>A p.H436Q | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.853); catalogued as COSV67256103; called by muse, mutect2, varscan2
- DLG4 | c.1784C>T p.A595V (on ENST00000399506 / NM_001321075.3; = p.A638V on NM_001365.4) | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs368908045; called by muse, mutect2, varscan2
- H2AC1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.588); catalogued as rs762868475, COSV51236783, COSV51238650; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 98/218 reads (45%) | catalogued as rs181922188; called by muse, mutect2, varscan2
- ITIH1 | c.2614C>G p.Q872E | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56255519; called by muse, mutect2, varscan2
- KCNH2 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs199472972, CM057125, CM097472, COSV51231983; called by muse, mutect2
- KLHL5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/189 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs926772598; called by muse, mutect2, varscan2
- MAG | c.194A>C p.Y65S | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62700014; called by muse, mutect2
- MYO6 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs758421542; called by muse, mutect2, varscan2
- NEURL1B | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63940274; called by muse, mutect2, varscan2
- PCDHA9 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV65323072, COSV65328580; called by muse, mutect2
- PLCL1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 139/276 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771861039; called by muse, mutect2, varscan2
- PRKCE | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as rs1414785255, COSV60325956; called by muse, mutect2, varscan2
- RASA2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.75); catalogued as rs1394181436; called by muse, mutect2, varscan2
- RNF112 | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71327078; called by muse, mutect2, varscan2
- SOGA1 | c.4070G>A p.R1357H | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs546471320; called by muse, mutect2, varscan2
- ZNF366 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 137/588 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1486126542, COSV59218816; called by muse, mutect2, varscan2
- ZNF764 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99411233; called by muse, mutect2, varscan2
- ABCA4 | c.3367G>A p.A1123T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ABCA7 | c.3423+1G>A p.X1141_splice | Splice Site (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.1090+1G>C p.X364_splice | Splice Site (SNP) | VAF 12/346 reads (3%) | called by muse, mutect2
- ADGRV1 | c.11161C>G p.L3721V | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL136295.1 | c.1456G>C p.A486P | Missense Mutation (SNP) | VAF 124/570 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ALDH1L1 | c.2086A>C p.M696L | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ALG10B | c.1025A>C p.Y342S | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2
- APPBP2 | c.745T>G p.L249V | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPIFC | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BRDT | c.2373A>T p.Q791H | Missense Mutation (SNP) | VAF 103/213 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D1 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- DOCK8 | c.5280A>C p.E1760D | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- E2F2 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELAPOR2 | c.2992C>G p.Q998E (on ENST00000450689 / NM_001142749.3; = p.Q831E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- EVPL | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HERC6 | c.1679A>T p.K560I | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HTD2 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 22/760 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM4E | c.49A>C p.T17P | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KIF26A | c.5050G>C p.G1684R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- LMAN1 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 46/538 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPK8IP3 | c.980A>C p.N327T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MSH4 | c.245-1G>C p.X82_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2
- MTTP | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 29/148 reads (20%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- NANS | c.1064A>G p.K355R | Missense Mutation (SNP) | VAF 95/436 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- OMD | c.950T>A p.L317H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PAPPA2 | c.3322C>G p.H1108D | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PEX13 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PIEZO1 | c.4894G>C p.E1632Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLA2G3 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNMA5 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.03); called by muse, mutect2
- POLR3D | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRPF8 | c.2043T>A p.F681L | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2
- PTK2 | c.2603A>G p.D868G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBBP5 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- RBM10 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 101/103 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- RIPOR3 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- S1PR5 | c.175T>G p.L59V | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIRT7 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC17A4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLCO1A2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 5/150 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SP110 | c.960A>C p.Q320H | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- SPEN | c.9592A>G p.M3198V | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TENM1 | c.2248G>T p.D750Y | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- THSD7B | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMPRSS6 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRIO | c.3066+1G>T p.X1022_splice | Splice Site (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- UGT2B15 | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- VPS13B | c.1019A>T p.E340V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ZCRB1 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 123/476 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE9 | c.1477A>C p.K493Q | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF426 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 131/487 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF486 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- ADGRD2 | c.1968C>T p.T656= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as rs373807450; called by muse, mutect2, varscan2
- AJUBA | c.318C>T p.P106= | Silent (SNP) | VAF 34/183 reads (19%) | called by muse, mutect2, varscan2
- CPNE3 | c.1050G>A p.Q350= | Silent (SNP) | VAF 100/205 reads (49%) | called by muse, mutect2, varscan2
- CUBN | c.4596C>T p.S1532= | Silent (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- CXCR1 | c.499C>T p.L167= | Silent (SNP) | VAF 72/152 reads (47%) | called by muse, mutect2, varscan2
- DPM3 | c.90G>A p.L30= (on ENST00000341298; = p.L60= on NM_018973.3) | Silent (SNP) | VAF 69/226 reads (31%) | catalogued as rs144852184; called by muse, mutect2, varscan2
- EFTUD2 | c.945C>T p.S315= | Silent (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- EGFLAM | c.1077C>T p.V359= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as COSV59321049; called by muse, mutect2, varscan2
- GC | c.1062T>A p.T354= | Silent (SNP) | VAF 36/530 reads (7%) | catalogued as rs1477520391, COSV56739579; called by muse, mutect2
- GLI1 | c.3055C>T p.L1019= | Silent (SNP) | VAF 107/219 reads (49%) | called by muse, mutect2, varscan2
- HTR2C | c.420G>A p.A140= | Silent (SNP) | VAF 196/201 reads (98%) | catalogued as rs200457900, COSV52213029; called by muse, mutect2, varscan2
- IGFBP7 | c.423G>A p.E141= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs976660228; called by muse, mutect2
- NLRP6 | c.333G>A p.T111= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as rs1399518596; called by muse, mutect2, varscan2
- NOXRED1 | c.426C>A p.L142= | Silent (SNP) | VAF 135/224 reads (60%) | catalogued as COSV53628504; called by muse, mutect2, varscan2
- NYAP2 | c.1257G>A p.T419= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as rs774623727, COSV56000714; called by muse, mutect2, varscan2
- PCDH10 | c.2412A>T p.I804= | Silent (SNP) | VAF 232/348 reads (67%) | called by muse, mutect2, varscan2
- PPP1R10 | c.819C>A p.T273= | Silent (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- RHBDL3 | c.768C>T p.A256= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs201038477; called by muse, varscan2
- SAFB | c.309C>T p.N103= | Silent (SNP) | VAF 21/226 reads (9%) | catalogued as rs145844588, COSV52649754; called by muse, mutect2
- STOML1 | c.279G>T p.L93= | Silent (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- TCTEX1D4 | c.225G>C p.G75= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- ZNF410 | c.198C>T p.S66= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs1244899245; called by muse, mutect2, varscan2
- ZNF416 | c.414G>A p.Q138= | Silent (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- ZNF843 | c.519C>T p.C173= | Silent (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- AC233702.1 | n.97G>A | RNA (SNP) | VAF 81/198 reads (41%) | catalogued as rs77669044; called by muse, mutect2, varscan2
- ANGPT2 | c.*2223C>G | 3'UTR (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- ARAP1 | c.4185+104A>C | Intron (SNP) | VAF 41/222 reads (18%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-180651C>G | Intron (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- ATP2C1 | c.-227C>T | 5'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ATP8B1 | c.1221-42G>C | Intron (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2, varscan2
- BLOC1S6 | c.82+273T>C | Intron (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- BTLA | c.*1070A>G | 3'UTR (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- CARM1 | c.1684+54G>A | Intron (SNP) | VAF 36/126 reads (29%) | catalogued as rs546866384; called by muse, mutect2, varscan2
- CASP3 | c.*1267C>T | 3'UTR (SNP) | VAF 21/90 reads (23%) | catalogued as rs892050662; called by muse, mutect2, varscan2
- CCDC134 | c.*498G>A | 3'UTR (SNP) | VAF 35/85 reads (41%) | catalogued as rs1365194823; called by muse, mutect2, varscan2
- CDH11 | c.*926C>A | 3'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- CDKN2B | c.*1675C>A | 3'UTR (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- CEP170 | c.1843+302T>A | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs2789178; called by muse, mutect2
- CLN6 | c.*574G>C | 3'UTR (SNP) | VAF 46/183 reads (25%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.*2920A>T | 3'UTR (SNP) | VAF 44/192 reads (23%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12171C>T | Intron (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- DACT3 | c.500-871G>T | Intron (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+2035A>G | Intron (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- DISC1 | c.1981+36451A>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- DPP8 | c.*3492G>A | 3'UTR (SNP) | VAF 24/108 reads (22%) | catalogued as rs946092042; called by muse, mutect2, varscan2
- DSC1 | c.*649G>T | 3'UTR (SNP) | VAF 42/220 reads (19%) | called by muse, mutect2, varscan2
- DST | chr6:56458149 T>G | 3'Flank (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- ERBB4 | c.*1035C>T | 3'UTR (SNP) | VAF 100/214 reads (47%) | called by muse, mutect2, varscan2
- EXTL2 | c.*1392A>G | 3'UTR (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- FAF2 | c.*224A>C | 3'UTR (SNP) | VAF 124/603 reads (21%) | called by muse, mutect2, varscan2
- FAM120C | c.*1926G>A | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- FKBP9 | c.*421T>C | 3'UTR (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- GMEB1 | chr1:28717890 A>C | 3'Flank (SNP) | VAF 52/144 reads (36%) | called by muse, mutect2, varscan2
- GORASP1 | c.917-118C>T | Intron (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- HAUS6P3 | n.136G>C | RNA (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*1622C>G | 3'UTR (SNP) | VAF 70/224 reads (31%) | called by muse, mutect2, varscan2
- IGHM | chr14:105859544 G>A | 5'Flank (SNP) | VAF 24/25 reads (96%) | catalogued as rs140174493; called by muse, varscan2
- IL4I1 | chr19:49901704 T>C | 5'Flank (SNP) | VAF 120/262 reads (46%) | called by muse, mutect2
- KHK | c.210-84C>T | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs1002194243; called by muse, mutect2, varscan2
- LARP1 | c.*2052C>T | 3'UTR (SNP) | VAF 107/348 reads (31%) | called by muse, mutect2, varscan2
- LINC02418 | n.1463_1464insCTT | RNA (INS) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- MED13L | c.5364+307G>A | Intron (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- MIER1 | c.*2631T>G | 3'UTR (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- MYCL | c.*670G>T | 3'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- NACC2 | c.*1082C>T | 3'UTR (SNP) | VAF 181/275 reads (66%) | catalogued as rs369293144; called by muse, mutect2
- NAV1 | c.*6027G>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*8368A>G | 3'UTR (SNP) | VAF 113/233 reads (48%) | called by muse, mutect2, varscan2
- OSBPL2 | c.*1535C>T | 3'UTR (SNP) | VAF 27/158 reads (17%) | catalogued as rs191339755; called by muse, mutect2, varscan2
- OTULIN | c.*5264A>G | 3'UTR (SNP) | VAF 62/341 reads (18%) | called by muse, mutect2, varscan2
- P2RY1 | c.*646G>A | 3'UTR (SNP) | VAF 34/118 reads (29%) | catalogued as rs1351084237; called by muse, mutect2, varscan2
- PAPPA2 | c.-84A>T | 5'UTR (SNP) | VAF 113/360 reads (31%) | called by muse, mutect2, varscan2
- PCMTD1 | chr8:51899125 C>A | 5'Flank (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- PHACTR2 | c.1812+66C>T | Intron (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.*149T>C | 3'UTR (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- PPA2 | c.*524T>G | 3'UTR (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.*2342C>A | 3'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- PURA | c.*1175T>G | 3'UTR (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- RAB8B | c.*728G>A | 3'UTR (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- RNF40 | c.*1836G>C | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55682228 A>G | 5'Flank (SNP) | VAF 26/353 reads (7%) | called by muse, mutect2
- RPLP1 | c.72+10G>C | Intron (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- RSPO1 | c.*165A>G | 3'UTR (SNP) | VAF 88/237 reads (37%) | called by muse, mutect2, varscan2
- RTL4 | c.*357T>C | 3'UTR (SNP) | VAF 66/66 reads (100%) | called by muse, mutect2, varscan2
- SETD7 | c.*2853G>A | 3'UTR (SNP) | VAF 73/240 reads (30%) | called by muse, mutect2, varscan2
- SFR1 | c.*84T>G | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+15791C>A | Intron (SNP) | VAF 77/86 reads (90%) | catalogued as rs1468573807, COSV99683551; called by muse, mutect2, varscan2
- SLC1A7 | c.432-2582A>C | Intron (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- SPATA13 | c.*155G>A | 3'UTR (SNP) | VAF 167/547 reads (31%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*1401T>C | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- STRN3 | c.*376T>C | 3'UTR (SNP) | VAF 274/472 reads (58%) | catalogued as COSV99363597; called by muse, varscan2
- SV2C | c.*2360C>T | 3'UTR (SNP) | VAF 214/342 reads (63%) | called by muse, mutect2
- SYTL4 | c.1184+105G>C | Intron (SNP) | VAF 38/70 reads (54%) | catalogued as COSV99342632; called by muse, mutect2, varscan2
- TCP1 | c.*57T>A | 3'UTR (SNP) | VAF 126/384 reads (33%) | called by muse, mutect2
- TM2D1 | c.166+34A>C | Intron (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- TMEM50B | c.-42+812dup | Intron (INS) | VAF 10/34 reads (29%) | catalogued as rs1303251245; called by pindel, varscan2
- TMEM50B | c.-42+806C>G | Intron (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- TYRP1 | c.*993G>A | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- UBXN10 | c.*487G>A | 3'UTR (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- UBXN4 | c.*1975_*1984delinsAGTACATGGT | 3'UTR (ONP) | VAF 20/112 reads (18%) | called by pindel, varscan2*
- USP33 | c.*991G>A | 3'UTR (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- WDR82 | c.-55C>G | 5'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- ZNF516 | c.*2365C>T | 3'UTR (SNP) | VAF 23/276 reads (8%) | catalogued as rs908383924; called by muse, mutect2
- ZNF789 | c.151+563A>T | Intron (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
